Gene-level copy-number profile of tumor specimen TCGA-CV-6003-01A from TCGA case TCGA-CV-6003, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 50.9 years (18,600 days).
Specimen TCGA-CV-6003-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.802a4118-7c45-4ddb-80ae-f4543183b79b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-6003-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/246a64e7-3ae2-4918-8d99-b2eec41f5a89

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 7,984; copy number 3: 22,709; copy number 4: 17,740; copy number 5: 6,382; copy number 6: 4,482; copy number 8: 309; copy number 10: 6; copy number 11: 36; copy number 16: 1; copy number 20: 166; copy number 39: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-6003-01A-11D-1682-01): tumor purity 0.56, ploidy 3.5, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 521 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:45,254,948–45,895,970, 4 genes, copy number 8–16: HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr8:118,923,557–128,564,679, 165 genes, copy number 8–10 (broad region; genes not listed).
- chr11:63,369,785–64,451,657, 61 genes, copy number 8 (broad region; genes not listed).
- chr20:31,257,664–40,126,357, 291 genes, copy number 8–39 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
